Somatic mutation profile of tumor specimen TCGA-44-2668-01A (aliquot TCGA-44-2668-01A-01W-0928-08) from TCGA case TCGA-44-2668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.6 years (18,856 days).
Specimen TCGA-44-2668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d5f2b7e-98c9-4bd1-b139-fd1a21747056.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2668-10A (Blood Derived Normal), aliquot TCGA-44-2668-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e83b9578-ff82-4210-9468-64c792876884

The open-access MAF lists 410 somatic variants for this specimen: 310 protein-altering or splice-affecting, 95 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 95, Nonsense Mutation 25, Splice Site 11, Frame Shift Del 9, Splice Region 3, Intron 2, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs376370716; called by muse, mutect2, varscan2
- ACER2 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 124/704 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820950; called by muse, mutect2, varscan2
- ADAMTS19 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50757482; called by muse, mutect2
- ADAMTS20 | c.4640G>A p.C1547Y | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67133587; called by muse, mutect2, varscan2
- ADAMTS4 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 51/361 reads (14%) | catalogued as COSV63488058; called by muse, mutect2, varscan2
- ADCY2 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 31/227 reads (14%) | catalogued as COSV57879098; called by muse, mutect2, varscan2
- ADGRB3 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65401825; called by muse, mutect2, varscan2
- ADGRE1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV51677006; called by muse, mutect2
- AFF2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60669144; called by mutect2, varscan2
- AHI1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 54/922 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV55629204; called by muse, mutect2
- AMOT | c.2416A>T p.T806S (on ENST00000371959 / NM_001113490.1; = p.T397S on NM_133265.3) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV59064774; called by muse, mutect2, varscan2
- ANGEL1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1356414829, COSV51873956; called by muse, mutect2, varscan2
- ANGPT4 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 94/633 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67921955; called by muse, mutect2, varscan2
- ANK2 | c.9628A>G p.T3210A | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV52168144; called by muse, mutect2, varscan2
- ANKFN1 | c.1624C>G p.H542D | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV59450694; called by muse, mutect2, varscan2
- ANKH | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52482285, COSV99414490; called by muse, mutect2, varscan2
- ARGLU1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62271695, COSV62271857; called by muse, mutect2, varscan2
- ARHGEF7 | c.988G>T p.V330L (on ENST00000375741 / NM_001113511.2; = p.V152L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs752939884, COSV54545313, COSV54549428; called by muse, mutect2
- ARHGEF7 | c.1533G>C p.L511F (on ENST00000375741 / NM_001113511.2; = p.L333F on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54545336; called by muse, mutect2, varscan2
- ASIC4 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61732282; called by muse, mutect2, varscan2
- ATP8A2 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54958704; called by muse, mutect2, varscan2
- ATR | c.6480G>C p.L2160F | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63384624; called by muse, mutect2, varscan2
- BCHE | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV52258139; called by muse, mutect2, varscan2
- BEST4 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 57/385 reads (15%) | catalogued as rs138830699; called by muse, mutect2, varscan2
- BMP10 | c.631del p.Q211Kfs*29 | Frame Shift Del (DEL) | VAF 30/246 reads (12%) | catalogued as COSV54895014; called by mutect2, pindel, varscan2
- BPIFB6 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100848489; called by muse, mutect2
- BTN2A1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201411917, COSV57004085; called by muse, mutect2, varscan2
- C10orf90 | c.1908C>G p.F636L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52956156, COSV52957468; called by muse, mutect2, varscan2
- C1orf105 | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62959489; called by muse, varscan2
- C4orf17 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV58512810; called by muse, mutect2, varscan2
- C9orf64 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 40/263 reads (15%) | catalogued as COSV59032715; called by muse, mutect2, varscan2
- CASP4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67744530; called by muse, mutect2, varscan2
- CCDC178 | c.2148G>C p.E716D (on ENST00000383096 / NM_001105528.3; = p.E678D on NM_198995.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV55778957; called by muse, mutect2, varscan2
- CCDC28A | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs143442772; called by muse, mutect2, varscan2
- CCDC57 | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV66433924, COSV66434564; called by muse, mutect2, varscan2
- CD200R1 | c.307G>T p.E103* (on ENST00000471858 / NM_170780.3; = p.E126* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 134/674 reads (20%) | catalogued as COSV55601504; called by muse, mutect2, varscan2
- CDH10 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52584948; called by muse, mutect2, varscan2
- CDH6 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54071180, COSV54072095; called by muse, mutect2, varscan2
- CDH6 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54072103; called by muse, mutect2, varscan2
- CDH7 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59888138; called by muse, mutect2, varscan2
- CEP20 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as COSV55384481; called by muse, mutect2, varscan2
- CFI | c.1045-2A>T p.X349_splice | Splice Site (SNP) | VAF 33/214 reads (15%) | catalogued as COSV67098982; called by muse, mutect2, varscan2
- CHD4 | c.3520G>C p.V1174L (on ENST00000357008 / NM_001363606.2; = p.V1187L on NM_001273.5) | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV58903691; called by muse, mutect2
- CHD8 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.428); catalogued as COSV101303091; called by muse, mutect2
- CHD9 | c.5581A>T p.R1861* | Nonsense Mutation (SNP) | VAF 41/193 reads (21%) | catalogued as COSV54611874; called by muse, mutect2, varscan2
- CHRM3 | c.1592G>C p.W531S | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2, varscan2
- CHRM3 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108107, COSV99697992; called by muse, mutect2, varscan2
- CLRN2 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV72512587; called by muse, mutect2, varscan2
- CNTN3 | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 72/594 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV55175046; called by muse, mutect2, varscan2
- CNTNAP2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.184); catalogued as COSV62201650; called by muse, mutect2, varscan2
- CNTNAP5 | c.3050C>A p.P1017H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV70472805; called by muse, mutect2, varscan2
- COBL | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.386); catalogued as COSV54348893; called by muse, varscan2
- COG5 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51754667; called by muse, mutect2, varscan2
- COL22A1 | c.3914C>G p.P1305R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100279666, COSV57342867; called by muse, mutect2, varscan2
- COL24A1 | c.2656del p.E886Kfs*50 | Frame Shift Del (DEL) | VAF 65/470 reads (14%) | catalogued as COSV65304056; called by mutect2, pindel, varscan2
- COL24A1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV100992999, COSV65308229; called by muse, mutect2
- COL4A6 | c.2780G>T p.G927V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859421, COSV57869363; called by muse, mutect2, varscan2
- COL4A6 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57869376; called by muse, mutect2, varscan2
- COL6A3 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780201464, COSV55094333; called by muse, mutect2, varscan2
- CSDE1 | c.1717A>G p.K573E (on ENST00000358528 / NM_001007553.3; = p.K542E on NM_007158.6) | Missense Mutation (SNP) | VAF 33/570 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54750316; called by muse, mutect2
- CSMD3 | c.8710G>C p.G2904R (on ENST00000297405 / NM_001363185.1; = p.G2735R on NM_052900.3) | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213938; called by muse, mutect2
- CSMD3 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.761); catalogued as COSV52213955; called by muse, mutect2, varscan2
- CSMD3 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52213979; called by muse, mutect2, varscan2
- CYP4F2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 98/783 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV50001627; called by muse, mutect2, varscan2
- DCT | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV65469687; called by muse, mutect2, varscan2
- DDX11 | c.1955T>G p.V652G | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506006, COSV52507585; called by muse, mutect2, varscan2
- DERL1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52365157; called by muse, mutect2, varscan2
- DHRSX | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 22/135 reads (16%) | catalogued as COSV58135095; called by muse, mutect2, varscan2
- DHTKD1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53804398, COSV53806440; called by muse, mutect2
- DHX32 | c.177A>T p.R59S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52941025; called by muse, mutect2, varscan2
- DIAPH3 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57368044; called by muse, mutect2, varscan2
- DLGAP2 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.147); catalogued as COSV70099886; called by muse, mutect2, varscan2
- DLGAP2 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70099892; called by muse, mutect2
- DNAH1 | c.11593G>A p.D3865N | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56235798; called by muse, varscan2
- DNAH9 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV52356054; called by muse, mutect2, varscan2
- DNAH9 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201122944, COSV52356066; called by muse, mutect2, varscan2
- DOCK2 | c.5153C>A p.S1718* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV56945133, COSV56965266; called by muse, mutect2, varscan2
- DPP6 | c.2512T>A p.S838T (on ENST00000377770 / NM_001364500.2; = p.S776T on NM_001936.5) | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV59622580; called by muse, varscan2
- DROSHA | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV60777911; called by muse, mutect2, varscan2
- DSC3 | c.631T>C p.L211= | Splice Region (SNP) | VAF 10/89 reads (11%) | catalogued as COSV64573557; called by muse, mutect2
- DUSP6 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54378990; called by muse, mutect2, varscan2
- DYDC2 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV55472654; called by muse, mutect2, varscan2
- EIF2D | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55114118; called by muse, mutect2, varscan2
- EPHA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56036407; called by muse, mutect2, varscan2
- EPHA6 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67577491; called by muse, mutect2, varscan2
- ERICH3 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58603768; called by muse, mutect2, varscan2
- ERICH3 | c.1850G>C p.R617T | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58609992, COSV58620417; called by muse, mutect2, varscan2
- ERICH6 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55799476, COSV55801319; called by muse, mutect2, varscan2
- ESD | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66340464, COSV66340808; called by muse, mutect2, varscan2
- FAAP24 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54280597; called by muse, mutect2
- FAM124B | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 33/269 reads (12%) | catalogued as COSV66272581; called by muse, mutect2, varscan2
- FAM135B | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs371759322, COSV50532393; called by muse, mutect2
- FAM171A1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65317027; called by muse, mutect2, varscan2
- FANK1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as rs141545587; called by muse, mutect2, varscan2
- FAT3 | c.5623G>A p.D1875N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as COSV53127603; called by muse, mutect2, varscan2
- FAT4 | c.5533G>T p.V1845L | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV58691310, COSV58700791; called by muse, mutect2, varscan2
- FATE1 | c.265A>T p.R89* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV64849047; called by muse, mutect2, varscan2
- FBN2 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV52496714; called by muse, mutect2, varscan2
- FBXO40 | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57524928; called by muse, mutect2, varscan2
- FGF5 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV56890586; called by muse, mutect2, varscan2
- FHOD3 | c.3458C>A p.S1153* (on ENST00000359247 / NM_001281739.3; = p.S1170* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 47/372 reads (13%) | catalogued as COSV57176969; called by muse, mutect2, varscan2
- FLG | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 6/145 reads (4%) | catalogued as COSV100911557, COSV64243248; called by muse, mutect2
- FLVCR2 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53162934; called by muse, mutect2, varscan2
- FNDC1 | c.2791T>A p.S931T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV51940473; called by muse, mutect2, varscan2
- FRZB | c.479-2A>T p.X160_splice | Splice Site (SNP) | VAF 59/265 reads (22%) | catalogued as COSV54554602; called by muse, mutect2, varscan2
- GABBR2 | c.1124C>A p.T375K | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV52308181; called by muse, mutect2, varscan2
- GC | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56737977; called by muse, mutect2, varscan2
- GDF5 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65501945; called by muse, mutect2, varscan2
- GFI1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); catalogued as rs776025480, COSV54043001; called by muse, mutect2, varscan2
- GFPT1 | c.1510G>T p.V504L (on ENST00000357308 / NM_001244710.2; = p.V486L on NM_002056.4) | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV61948621; called by muse, mutect2, varscan2
- GIMAP8 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV56232210; called by muse, mutect2
- GLI1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.691); catalogued as rs267603605, COSV57363662; called by muse, mutect2, varscan2
- GLP2R | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52326159; called by muse, mutect2, varscan2
- GMIP | c.551A>T p.K184I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV52557322; called by muse, mutect2, varscan2
- GNA13 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.17); catalogued as COSV71474582, COSV71474880; called by muse, mutect2
- GRID2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56220748; called by muse, mutect2, varscan2
- GRID2 | c.2083G>T p.G695* | Nonsense Mutation (SNP) | VAF 27/186 reads (15%) | catalogued as COSV56178049, COSV56220754; called by muse, mutect2, varscan2
- GRK5 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64866728; called by muse, mutect2, varscan2
- GRM7 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV63148841; called by muse, mutect2, varscan2
- GYS2 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV53924634; called by muse, mutect2, varscan2
- H3C12 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV58152941; called by muse, mutect2
- HBD | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 56/472 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV53082946, COSV53083332; called by muse, mutect2, varscan2
- HCST | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 67/447 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52887938; called by muse, mutect2, varscan2
- HERC2 | c.3766G>T p.D1256Y | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55329569, COSV55343146; called by muse, mutect2, varscan2
- HIPK2 | c.3031G>T p.G1011C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV101301612, COSV69210173; called by muse, mutect2
- IFI16 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55535430; called by muse, mutect2, varscan2
- IGHV3-20 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 52/426 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782671152; called by muse, mutect2
- IL9R | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753927767, COSV99729579; called by muse, mutect2, varscan2
- IMMT | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480837; called by muse, mutect2, varscan2
- ITGA11 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59878749; called by muse, mutect2, varscan2
- ITGA8 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65230549; called by muse, mutect2, varscan2
- ITGAX | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 26/185 reads (14%) | catalogued as COSV51647027, COSV51651894; called by muse, mutect2, varscan2
- ITGAX | c.2976+1G>T p.X992_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51647036; called by muse, mutect2, varscan2
- ITPR1 | c.4798A>C p.I1600L (on ENST00000354582; = p.I1585L on NM_002222.7) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV56986846; called by muse, mutect2, varscan2
- KATNIP | c.4259G>T p.G1420V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265663435, COSV55183565; called by muse, mutect2, varscan2
- KCNT2 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54086765, COSV54100416; called by muse, mutect2, varscan2
- KDM6B | c.2484del p.P829Lfs*65 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV54679083; called by mutect2, pindel, varscan2
- KMT2D | c.5837G>C p.G1946A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56453057; called by muse, mutect2, varscan2
- KNDC1 | c.3977G>T p.W1326L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58839924; called by muse, mutect2, varscan2
- KPNB1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51597852; called by muse, mutect2
- KRTAP8-1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); catalogued as COSV61598105; called by muse, mutect2
- LAMA1 | c.8866G>T p.G2956C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67539038; called by muse, mutect2
- LCE3E | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV64231901; called by muse, mutect2, varscan2
- LRP1B | c.10760G>T p.C3587F | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67236080; called by muse, varscan2
- LRRC15 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV61649919; called by muse, mutect2, varscan2
- LRRC6 | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV51543455; called by muse, mutect2, varscan2
- LRRN2 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV65784108; called by muse, mutect2, varscan2
- LSP1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV61135286; called by muse, mutect2
- LTBP2 | c.830+1G>T p.X277_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | catalogued as COSV56209738; called by muse, mutect2, varscan2
- LYPLAL1 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 40/282 reads (14%) | catalogued as COSV65106842; called by muse, mutect2, varscan2
- MACROD2 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54002065, COSV99428448; called by muse, mutect2, varscan2
- MARK1 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65068372; called by muse, mutect2, varscan2
- MAT1A | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64746039; called by muse, mutect2, varscan2
- MCF2L2 | c.1501A>T p.K501* | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | catalogued as COSV61055553; called by muse, mutect2, varscan2
- MGAM | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV71885618; called by muse, mutect2, varscan2
- MMD | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV50435153; called by muse, mutect2
- MMP16 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54171236; called by muse, mutect2, varscan2
- MMP20 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV52776296; called by muse, mutect2, varscan2
- MMRN1 | c.2391C>G p.N797K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs981596032, COSV53338753; called by muse, mutect2, varscan2
- MRC2 | c.2034A>T p.K678N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57640880; called by muse, mutect2, varscan2
- MTMR6 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67808682; called by muse, mutect2, varscan2
- MUC16 | c.31696G>C p.E10566Q | Missense Mutation (SNP) | VAF 90/644 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as COSV67474289; called by muse, mutect2, varscan2
- MUC16 | c.29537C>G p.T9846S | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV67474293; called by muse, mutect2, varscan2
- MYH1 | c.2248C>A p.L750M | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99875467; called by muse, mutect2
- MYH13 | c.3732G>C p.K1244N | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52832420; called by muse, mutect2, varscan2
- MYH2 | c.5595G>T p.K1865N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55433970, COSV99820946; called by muse, mutect2, varscan2
- MYH2 | c.4684G>T p.G1562* | Nonsense Mutation (SNP) | VAF 33/260 reads (13%) | catalogued as COSV55440845; called by muse, mutect2, varscan2
- MYO1C | c.586A>T p.S196C (on ENST00000648651 / NM_001080779.2; = p.S161C on NM_033375.5) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62999542; called by muse, mutect2, varscan2
- MYOCD | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58505663; called by muse, mutect2, varscan2
- NAA16 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65065520; called by muse, mutect2, varscan2
- NOL6 | c.1779G>T p.Q593H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53042866; called by muse, mutect2, varscan2
- NPAP1 | c.2910T>G p.S970R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV61508148; called by muse, mutect2, varscan2
- NPHS2 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV62635747; called by muse, mutect2
- NSRP1 | c.897T>G p.S299R | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55934240; called by muse, mutect2, varscan2
- NTNG1 | c.1166A>C p.H389P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV64273648, COSV64278211; called by muse, mutect2
- NUDCD1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53457805; called by muse, mutect2, varscan2
- NUFIP2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56604041; called by muse, mutect2, varscan2
- OCA2 | c.1823_1824insA p.Q609Pfs*8 | Frame Shift Ins (INS) | VAF 27/238 reads (11%) | catalogued as COSV100667355; called by mutect2, pindel, varscan2
- OCA2 | c.1594T>A p.W532R | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV62348883; called by muse, mutect2, varscan2
- OMD | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65020284; called by muse, mutect2, varscan2
- OR11H4 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 81/270 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59560447; called by muse, mutect2, varscan2
- OR1N1 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59196001; called by muse, mutect2, varscan2
- OR2M5 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 420/1620 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV63546498; called by muse, mutect2, varscan2
- OR2T34 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 75/612 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- OR2T6 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV63216560; called by muse, mutect2, varscan2
- OR4C3 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV60587131; called by muse, mutect2, varscan2
- OR4P4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV58922531; called by muse, mutect2, varscan2
- OR51D1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62914311, COSV62914347; called by muse, mutect2, varscan2
- OR51L1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 59/442 reads (13%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as rs150980273; called by muse, mutect2, varscan2
- OR5L1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61734348; called by muse, mutect2, varscan2
- OR5M3 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 69/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs973923348, COSV56567255; called by muse, mutect2, varscan2
- OR6F1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57468272, COSV57469037; called by muse, mutect2, varscan2
- OR8B8 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60144900; called by muse, mutect2, varscan2
- OVCH1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs745853862, COSV58964568; called by muse, varscan2
- PACSIN3 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066424; called by muse, mutect2, varscan2
- PASD1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV64854226, COSV64855802; called by muse, mutect2, varscan2
- PASD1 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV64855806; called by muse, mutect2, varscan2
- PAX2 | c.998T>A p.M333K (on ENST00000428433 / NM_003987.5; = p.M310K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV62291582; called by muse, mutect2, varscan2
- PAX4 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58387547, COSV58389431; called by muse, mutect2, varscan2
- PAX7 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV64750877; called by muse, mutect2, varscan2
- PCDH10 | c.1759C>A p.R587S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.095); catalogued as COSV52088168, COSV52103034; called by muse, mutect2, varscan2
- PCDH11X | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.927); catalogued as COSV53476362; called by mutect2, varscan2
- PCDHB16 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV53364278, COSV53372418; called by muse, mutect2, varscan2
- PCDHB7 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); catalogued as COSV50772567, COSV50778733; called by muse, mutect2
- PCNX2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50814344; called by muse, mutect2, varscan2
- PDE10A | c.1105T>A p.Y369N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.679); catalogued as COSV63050056; called by muse, mutect2, varscan2
- PDGFRA | c.3096G>T p.E1032D | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57269695; called by muse, mutect2, varscan2
- PDSS2 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV64655629; called by muse, mutect2
- PEG3 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV55637266; called by muse, mutect2, varscan2
- PEX12 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56778315; called by muse, mutect2, varscan2
- PID1 | c.144G>T p.M48I (on ENST00000354069 / NM_001330156.1; = p.M46I on NM_017933.5) | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV62477267; called by muse, mutect2, varscan2
- PKHD1 | c.6972C>G p.I2324M | Missense Mutation (SNP) | VAF 123/854 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61881760; called by muse, mutect2, varscan2
- PLEKHH2 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV56756212; called by muse, mutect2, varscan2
- POLE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV57683006; called by muse, mutect2
- POLR2B | c.3346G>T p.V1116F | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV55274114, COSV55274330; called by muse, mutect2, varscan2
- POT1 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 64/426 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62930355, COSV62934021; called by muse, mutect2, varscan2
- PPP1R7 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV52145477; called by muse, mutect2, varscan2
- PPP2R2A | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV60097585; called by muse, mutect2, varscan2
- PRKG2 | c.462-2A>T p.X154_splice | Splice Site (SNP) | VAF 37/273 reads (14%) | catalogued as COSV52326354; called by muse, mutect2, varscan2
- PTCHD4 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59788020; called by muse, mutect2, varscan2
- PTK2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 17/215 reads (8%) | catalogued as COSV61787476; called by muse, mutect2
- PTPN9 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60724282; called by muse, mutect2, varscan2
- PTPRD | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61956710; called by muse, mutect2, varscan2
- RAB11FIP1 | c.372-2A>C p.X124_splice | Splice Site (SNP) | VAF 25/171 reads (15%) | catalogued as COSV54761114; called by muse, mutect2, varscan2
- RALGPS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52224631; called by muse, mutect2, varscan2
- RALYL | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV72822111, COSV72822148; called by muse, mutect2, varscan2
- RASSF8 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51454009, COSV51455341; called by muse, mutect2, varscan2
- REST | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58361264, COSV58361801; called by muse, mutect2, varscan2
- RGS20 | c.706C>A p.H236N (on ENST00000297313 / NM_170587.4; = p.H89N on NM_003702.4) | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52018327; called by muse, mutect2
- RPS6KB1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV56677694; called by muse, mutect2
- RUFY2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV61191497; called by muse, mutect2, varscan2
- RYR3 | c.11063C>A p.S3688Y (on ENST00000389232; = p.S3689Y on NM_001036.6) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66795325; called by muse, mutect2, varscan2
- RYR3 | c.14436A>T p.L4812F (on ENST00000389232; = p.L4813F on NM_001036.6) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV66784648, COSV66795340; called by muse, mutect2
- SAMD9L | c.160del p.D54Tfs*3 | Frame Shift Del (DEL) | VAF 84/538 reads (16%) | catalogued as COSV59083080; called by mutect2, pindel, varscan2
- SEMA6D | c.2255G>A p.G752E (on ENST00000316364 / NM_153618.2; = p.G690E on NM_020858.2) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV60379103; called by muse, mutect2, varscan2
- SERPINA6 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58585717; called by muse, mutect2, varscan2
- SERPINB3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 27/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192213; called by muse, mutect2
- SERPINB8 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV54639938; called by muse, mutect2, varscan2
- SLC12A2 | c.3154T>A p.C1052S | Missense Mutation (SNP) | VAF 144/521 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52472668; called by muse, mutect2, varscan2
- SLC44A1 | c.761-1G>C p.X254_splice | Splice Site (SNP) | VAF 29/225 reads (13%) | catalogued as COSV58265339; called by muse, mutect2, varscan2
- SLC5A4 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 56/507 reads (11%) | catalogued as COSV56671279, COSV56671556; called by muse, mutect2, varscan2
- SLC6A5 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54228152; called by muse, mutect2
- SLC7A7 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV53537439; called by muse, mutect2, varscan2
- SNRNP48 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 44/317 reads (14%) | catalogued as COSV60939817; called by muse, mutect2, varscan2
- SPANXN3 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV65140477; called by muse, mutect2, varscan2
- SPIRE1 | c.1356G>C p.K452N (on ENST00000409402 / NM_001128626.2; = p.K438N on NM_020148.3) | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.234); catalogued as COSV59157949; called by muse, mutect2, varscan2
- SPOCK3 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.341); catalogued as COSV62722389; called by muse, mutect2, varscan2
- SPTA1 | c.6897C>A p.C2299* | Nonsense Mutation (SNP) | VAF 27/195 reads (14%) | catalogued as COSV63755124; called by muse, mutect2, varscan2
- SSX3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53644495; called by muse, mutect2, varscan2
- STARD10 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV58325889; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3176C>T p.T1059I | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59132255; called by muse, mutect2, varscan2
- STOX1 | c.2363G>T p.R788M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV53815652; called by muse, mutect2, varscan2
- SYN3 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 61/419 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV60510415; called by muse, mutect2, varscan2
- SYNE3 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62080249, COSV62084242; called by muse, mutect2, varscan2
- TAF1L | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 141/860 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774366817, COSV54261717; called by muse, mutect2, varscan2
- TBC1D1 | c.2322G>T p.W774C | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790920; called by muse, mutect2, varscan2
- TBC1D1 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 38/303 reads (13%) | catalogued as COSV99790924; called by muse, mutect2, varscan2
- TBC1D8 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65213491; called by muse, mutect2, varscan2
- TDRD5 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 67/599 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54242966; called by muse, mutect2, varscan2
- TLL2 | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100780550, COSV63573287, COSV63575956; called by muse, mutect2, varscan2
- TLN2 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV60891090; called by muse, mutect2, varscan2
- TMEM132B | c.3073A>T p.K1025* | Nonsense Mutation (SNP) | VAF 46/163 reads (28%) | catalogued as COSV54757343; called by muse, mutect2, varscan2
- TMEM168 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs752852979, COSV57181167; called by muse, mutect2, varscan2
- TMPRSS3 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52304286; called by muse, mutect2
- TMPRSS6 | c.1155T>A p.D385E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60979940; called by muse, mutect2, varscan2
- TP53INP1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV61331620, COSV61331826; called by muse, mutect2, varscan2
- TPX2 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 316/1040 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778633428, COSV55920304; called by muse, mutect2, varscan2
- TRAM1L1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV60292107, COSV60292308; called by muse, mutect2, varscan2
- TRIM29 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs767499147, COSV59280375, COSV59280957; called by muse, mutect2, varscan2
- TRIM69 | c.1499A>T p.Q500L (on ENST00000329464 / NM_182985.5; = p.Q341L on NM_080745.5) | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV57804112; called by muse, mutect2, varscan2
- TUBA8 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV57813279; called by muse, mutect2, varscan2
- UGT2B7 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV59443915; called by muse, mutect2, varscan2
- USH2A | c.7657T>A p.W2553R | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56386959; called by muse, mutect2, varscan2
- USH2A | c.5399G>C p.W1800S | Missense Mutation (SNP) | VAF 232/836 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149920, COSV56386971; called by muse, varscan2
- USH2A | c.5354C>G p.T1785R | Missense Mutation (SNP) | VAF 134/1096 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56386983; called by muse, varscan2
- USH2A | c.3800C>T p.A1267V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768141777, COSV56384831; called by muse, mutect2
- USP32 | c.4753G>T p.D1585Y | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56270778; called by muse, mutect2, varscan2
- USP9X | c.5015G>T p.R1672M | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61070852; called by muse, mutect2, varscan2
- USPL1 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55000457; called by muse, mutect2, varscan2
- VIRMA | c.4792A>G p.T1598A | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52586517; called by muse, mutect2, varscan2
- WDPCP | c.2191-1G>T p.X731_splice | Splice Site (SNP) | VAF 11/116 reads (9%) | catalogued as COSV99704738; called by muse, mutect2, varscan2
- WDR6 | c.1731C>G p.C577W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); catalogued as COSV58245454; called by muse, mutect2, varscan2
- WIPI1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50930357; called by muse, mutect2, varscan2
- WWTR1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs763418690, COSV62291763; called by muse, mutect2, varscan2
- XIRP2 | c.3602A>T p.Q1201L (on ENST00000628543; = p.Q1376L on NM_152381.6) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54709516; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 81/513 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54297140; called by muse, mutect2, varscan2
- ZC3HAV1 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV54297154; called by muse, mutect2
- ZFPM2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV65874291; called by muse, mutect2, varscan2
- ZNF479 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58639794; called by muse, mutect2
- ZNF479 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58639805; called by muse, mutect2, varscan2
- ATR | c.6898-3del | Splice Region (DEL) | VAF 18/129 reads (14%) | called by mutect2, pindel, varscan2
- CCL14 | c.236G>T p.S79I (on ENST00000618404 / NM_032963.4; = p.S95I on NM_032962.4) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2
- DYNC1H1 | c.9124_9126dup p.L3042dup | In Frame Ins (INS) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- FAT1 | c.12598del p.V4200Ffs*6 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, varscan2
- HEATR9 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IGKV2D-28 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by mutect2, varscan2
- INSRR | c.2239del p.A747Qfs*28 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- LINC01559 | n.400G>T | Splice Region (SNP) | VAF 38/404 reads (9%) | called by muse, mutect2
- PPRC1 | c.1219del p.L407Sfs*10 | Frame Shift Del (DEL) | VAF 28/225 reads (12%) | called by mutect2, pindel, varscan2
- RAB6D | c.555A>C p.R185S | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, varscan2
- ROBO2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- RPS4Y2 | c.272_274del p.S91del | In Frame Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
- SPR | c.402del p.T135Lfs*5 | Frame Shift Del (DEL) | VAF 22/157 reads (14%) | called by mutect2, pindel, varscan2
- TPTE | c.1136G>C p.S379T (on ENST00000618007 / NM_199261.4; = p.S361T on NM_199259.4) | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); called by muse, mutect2
- USH2A | c.389del p.G130Efs*15 | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | called by mutect2, varscan2
- ZNF98 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); called by mutect2, varscan2
- ABCG1 | c.894G>T p.R298= | Silent (SNP) | VAF 90/659 reads (14%) | catalogued as COSV59206032; called by muse, mutect2, varscan2
- ADGRG4 | c.6919C>A p.R2307= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as rs376547734, COSV54959019; called by muse, mutect2, varscan2
- ANO6 | c.1290G>A p.V430= | Silent (SNP) | VAF 146/651 reads (22%) | catalogued as rs1308184708, COSV57662771; called by muse, mutect2, varscan2
- APMAP | c.180G>T p.L60= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV54174675; called by muse, mutect2, varscan2
- ARHGAP25 | c.507A>G p.E169= (on ENST00000409202 / NM_001007231.3; = p.E161= on NM_014882.3) | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV54903808; called by muse, mutect2, varscan2
- ATP11C | c.2982A>G p.G994= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1297443682, COSV59566722; called by muse, mutect2, varscan2
- ATP8B2 | c.3243C>T p.P1081= (on ENST00000672630; = p.P1048= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 74/438 reads (17%) | catalogued as COSV59246625; called by muse, mutect2, varscan2
- BRINP2 | c.2268G>T p.V756= | Silent (SNP) | VAF 24/279 reads (9%) | catalogued as COSV64178207; called by muse, mutect2
- C1orf105 | c.441C>A p.P147= | Silent (SNP) | VAF 66/592 reads (11%) | catalogued as COSV62959495; called by muse, varscan2
- C1orf226 | c.444G>A p.L148= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV63395721; called by muse, mutect2, varscan2
- CASP4 | c.198T>C p.R66= | Silent (SNP) | VAF 43/306 reads (14%) | catalogued as rs1260480052, COSV67744533; called by muse, mutect2, varscan2
- CD1E | c.693T>C p.H231= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as rs1226448121, COSV63771412; called by muse, mutect2, varscan2
- CDH20 | c.279C>A p.S93= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV53006176, COSV53011939; called by muse, mutect2, varscan2
- CELSR2 | c.6909G>A p.T2303= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs150014940; called by muse, mutect2, varscan2
- CGNL1 | c.1047A>G p.S349= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs1360349045, COSV55569983; called by muse, mutect2, varscan2
- CNGA4 | c.981T>A p.P327= | Silent (SNP) | VAF 89/573 reads (16%) | catalogued as COSV66006266; called by muse, mutect2, varscan2
- CNTNAP2 | c.492G>T p.L164= | Silent (SNP) | VAF 35/318 reads (11%) | catalogued as COSV62201645; called by muse, mutect2, varscan2
- CTSC | c.1092G>A p.L364= | Silent (SNP) | VAF 69/459 reads (15%) | catalogued as COSV57058536; called by muse, mutect2, varscan2
- CYYR1 | c.30A>T p.P10= | Silent (SNP) | VAF 35/197 reads (18%) | catalogued as COSV54833623; called by muse, mutect2, varscan2
- DIAPH3 | c.432G>T p.R144= | Silent (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- DMRTA2 | c.942G>A p.R314= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV68672736; called by muse, mutect2, varscan2
- DNAI2 | c.969G>A p.L323= | Silent (SNP) | VAF 60/287 reads (21%) | catalogued as COSV56759550; called by muse, mutect2, varscan2
- DPEP2 | c.1431C>A p.A477= | Silent (SNP) | VAF 38/227 reads (17%) | catalogued as COSV52054913; called by muse, mutect2, varscan2
- ERBB2 | c.291G>A p.Q97= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as COSV54073487, COSV54085494; called by muse, mutect2, varscan2
- FAM107A | c.102G>T p.L34= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62980782; called by muse, mutect2, varscan2
- FAM163A | c.120C>A p.T40= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV59203667, COSV59204251; called by muse, mutect2, varscan2
- FMN2 | c.2388C>A p.V796= | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as COSV60435299; called by muse, mutect2, varscan2
- FOXP2 | c.993G>T p.S331= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100646128, COSV63488109; called by muse, mutect2
- GALNT7 | c.1104C>T p.T368= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1332696812, COSV53931379; called by muse, mutect2, varscan2
- GFRA3 | c.684G>T p.G228= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV51229096, COSV99218344; called by muse, mutect2, varscan2
- GFRAL | c.744G>A p.V248= | Silent (SNP) | VAF 101/641 reads (16%) | catalogued as rs748931694, COSV61232059; called by muse, mutect2, varscan2
- GHDC | c.723G>A p.R241= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV56988516; called by muse, mutect2, varscan2
- GPC6 | c.378G>T p.R126= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV65515967; called by muse, mutect2, varscan2
- GPR12 | c.436C>T p.L146= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV67344476; called by muse, mutect2, varscan2
- GPR61 | c.867C>A p.L289= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV63983960; called by muse, mutect2, varscan2
- GPRASP2 | c.2355G>A p.Q785= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as COSV59991699; called by muse, mutect2
- H2BW1 | c.468C>T p.S156= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs370071971, COSV54220528; called by muse, mutect2, varscan2
- HOXA5 | c.480G>A p.A160= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs202017218, COSV56073789; called by muse, mutect2, varscan2
- HPS4 | c.870A>T p.T290= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as COSV61103980; called by muse, mutect2
- HYDIN | c.14979C>A p.P4993= | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as COSV66639727; called by muse, mutect2, varscan2
- IL7R | c.1248C>G p.P416= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100286448, COSV57409599; called by muse, mutect2, varscan2
- IL9R | c.441G>C p.L147= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99729573; called by muse, mutect2, varscan2
- ITGAD | c.1779C>A p.L593= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV66758485; called by muse, mutect2, varscan2
- ITGAD | c.2595C>A p.P865= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV66758486; called by muse, mutect2, varscan2
- KCNA6 | c.276C>T p.S92= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV54976012; called by muse, mutect2
- KCNA6 | c.1038G>T p.L346= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs757378869, COSV54976019; called by muse, mutect2, varscan2
- KRBA1 | c.672G>T p.R224= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV55442140; called by muse, mutect2, varscan2
- LPL | c.1209C>G p.L403= | Silent (SNP) | VAF 72/399 reads (18%) | catalogued as COSV60931517; called by muse, mutect2, varscan2
- LRRC8C | c.1735C>T p.L579= | Silent (SNP) | VAF 33/288 reads (11%) | catalogued as COSV64998934; called by muse, mutect2, varscan2
- MATN1 | c.201C>A p.V67= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV65650868; called by muse, mutect2, varscan2
- MMP16 | c.729A>T p.V243= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV54171257; called by muse, mutect2, varscan2
- MS4A6E | c.30C>G p.T10= | Silent (SNP) | VAF 38/305 reads (12%) | catalogued as COSV55727249; called by muse, mutect2, varscan2
- MUC16 | c.11475A>C p.P3825= | Silent (SNP) | VAF 126/986 reads (13%) | catalogued as COSV101202441, COSV67474302; called by muse, mutect2, varscan2
- MYH1 | c.2247C>A p.L749= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV56850622, COSV99875468; called by muse, mutect2
- MYH6 | c.5313G>A p.L1771= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV59306383; called by muse, mutect2, varscan2
- MYOM3 | c.303G>A p.R101= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1201152247, COSV58395469; called by muse, mutect2
- NALCN | c.2109C>T p.I703= | Silent (SNP) | VAF 70/465 reads (15%) | catalogued as rs1019776644, COSV51943405; called by muse, mutect2, varscan2
- NIBAN3 | c.1959T>C p.S653= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV53109837; called by muse, mutect2, varscan2
- NLRP2 | c.2955C>T p.V985= | Silent (SNP) | VAF 39/208 reads (19%) | catalogued as COSV54756469; called by muse, mutect2, varscan2
- NOTCH4 | c.1842C>A p.L614= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as COSV66681582; called by muse, mutect2, varscan2
- NYNRIN | c.1986A>T p.A662= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV66843166; called by muse, mutect2, varscan2
- OBSCN | c.15381G>T p.V5127= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV52786502; called by mutect2, varscan2
- OR10G4 | c.321G>T p.G107= | Silent (SNP) | VAF 50/626 reads (8%) | catalogued as COSV57978507; called by muse, varscan2
- OR10X1 | c.903C>T p.I301= | Silent (SNP) | VAF 44/314 reads (14%) | catalogued as COSV63767237, COSV63767322; called by muse, mutect2, varscan2
- OR6V1 | c.168C>G p.P56= | Silent (SNP) | VAF 149/912 reads (16%) | catalogued as COSV69237394; called by muse, mutect2, varscan2
- OSBPL10 | c.675A>T p.A225= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV67340627; called by muse, mutect2, varscan2
- PARD3B | c.636A>T p.P212= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV62515986; called by muse, mutect2, varscan2
- PCDHAC2 | c.168G>A p.A56= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs782780798, COSV53851024; called by muse, mutect2, varscan2
- PDE6H | c.243G>A p.G81= | Silent (SNP) | VAF 75/294 reads (26%) | catalogued as COSV56760841; called by muse, mutect2, varscan2
- PKHD1L1 | c.2997A>G p.L999= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV65737613, COSV65745656; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>T p.G2768= | Silent (SNP) | VAF 40/345 reads (12%) | catalogued as COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PKNOX1 | c.813G>T p.T271= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV52336977; called by muse, mutect2, varscan2
- PRMT1 | c.702G>A p.E234= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV67159810; called by muse, mutect2, varscan2
- PTPRC | c.408C>T p.L136= | Silent (SNP) | VAF 44/482 reads (9%) | catalogued as rs1239293392, COSV61414078; called by muse, mutect2
- PTPRZ1 | c.288T>C p.H96= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV66439364; called by muse, mutect2, varscan2
- RSBN1 | c.1701C>T p.T567= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as rs960914700, COSV54733109; called by muse, mutect2, varscan2
- SALL2 | c.972C>T p.T324= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1181391004, COSV58103963; called by muse, mutect2, varscan2
- SCD5 | c.351C>T p.S117= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs936938166, COSV51103065; called by muse, mutect2, varscan2
- SERTAD2 | c.258C>T p.F86= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1261100399, COSV57640538; called by muse, mutect2, varscan2
- SH3BP5L | c.657C>T p.I219= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs759676523, COSV63539441; called by muse, mutect2, varscan2
- SLAIN2 | c.846C>G p.A282= | Silent (SNP) | VAF 60/388 reads (15%) | catalogued as COSV51907521; called by muse, mutect2, varscan2
- SLC5A1 | c.1077T>A p.V359= | Silent (SNP) | VAF 113/684 reads (17%) | catalogued as COSV56686288; called by muse, mutect2, varscan2
- SLC6A15 | c.549T>A p.P183= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV57022416, COSV57025231; called by muse, mutect2, varscan2
- SLC6A5 | c.507G>T p.V169= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV54228143; called by muse, mutect2, varscan2
- SMARCAD1 | c.1821G>T p.A607= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs111425618, COSV62774135, COSV62774909; called by muse, mutect2, varscan2
- SYDE2 | c.1467T>C p.N489= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV52316092; called by muse, mutect2
- SYPL2 | c.267C>A p.I89= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100881562, COSV63995040; called by muse, mutect2, varscan2
- TAS2R16 | c.690C>T p.A230= | Silent (SNP) | VAF 47/341 reads (14%) | catalogued as rs187186713, COSV50797402, COSV50799191; called by muse, mutect2, varscan2
- TFDP3 | c.1149A>G p.P383= | Silent (SNP) | VAF 84/284 reads (30%) | catalogued as COSV59537450; called by muse, mutect2
- THADA | c.1341G>A p.L447= | Silent (SNP) | VAF 31/222 reads (14%) | catalogued as COSV57686145; called by muse, mutect2, varscan2
- TTN | c.23082A>G p.S7694= (on ENST00000591111; = p.S6767= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/253 reads (6%) | catalogued as COSV60137327; called by muse, mutect2
- VPS13B | c.2388C>G p.L796= | Silent (SNP) | VAF 18/544 reads (3%) | catalogued as COSV62021161; called by muse, mutect2
- WDR89 | c.813A>G p.E271= | Silent (SNP) | VAF 120/587 reads (20%) | catalogued as COSV50827001; called by muse, mutect2, varscan2
- XIRP2 | c.8436G>A p.L2812= (on ENST00000628543; = p.L2987= on NM_152381.6) | Silent (SNP) | VAF 38/442 reads (9%) | catalogued as COSV54709527, COSV99747742; called by muse, mutect2
- ZNF536 | c.2151C>A p.P717= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV62826482; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822244 G>T | 5'Flank (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472260 G>T | 3'Flank (SNP) | VAF 45/272 reads (17%) | called by muse, mutect2, varscan2
- TMBIM6 | c.-31+550G>C | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as COSV57278519, COSV99920664; called by muse, mutect2, varscan2
- TNN | c.-74G>T | 5'UTR (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99511619; called by muse, mutect2, varscan2
- TRPM3 | c.979+16651G>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
